Somatic mutation profile of tumor specimen TCGA-B6-A0I8-01A (aliquot TCGA-B6-A0I8-01A-11W-A050-09) from TCGA case TCGA-B6-A0I8, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage X; Age at diagnosis: 46.7 years (17,073 days).
Specimen TCGA-B6-A0I8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a7a17d5-f136-49f7-b457-2a314d3c991d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0I8-10A (Blood Derived Normal), aliquot TCGA-B6-A0I8-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0d721fe-5411-4bd1-8052-72ba590591e1

The open-access MAF lists 124 somatic variants for this specimen: 88 protein-altering or splice-affecting, 34 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 34, Frame Shift Del 8, Splice Site 5, Nonsense Mutation 4, Intron 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.4279C>T p.R1427C (on ENST00000372530 / NM_001198934.2; = p.R1399C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as rs375273058; called by muse, mutect2, varscan2
- ANK2 | c.4279C>T p.R1427* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | catalogued as rs762339281, COSV100001534; called by muse, mutect2, varscan2
- ANK3 | c.8018C>T p.P2673L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55063140; called by muse, mutect2, varscan2
- ANKAR | c.3521C>G p.S1174C | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV55613954; called by muse, mutect2, varscan2
- ARHGAP12 | c.60A>T p.E20D | Missense Mutation (SNP) | VAF 76/450 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60964163; called by muse, mutect2, varscan2
- ASTN2 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 71/337 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.905); catalogued as rs868310841, COSV57755479; called by muse, mutect2, varscan2
- ATF2 | c.1501C>A p.Q501K | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.678); catalogued as COSV51370420; called by muse, mutect2, varscan2
- ATP8B4 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200382600; called by muse, mutect2, varscan2
- ATXN2 | c.1328A>C p.Q443P (on ENST00000550104; = p.Q283P on NM_002973.4) | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101112746; called by muse, mutect2
- ATXN2 | c.1326C>A p.N442K (on ENST00000550104; = p.N282K on NM_002973.4) | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.182); catalogued as COSV101112747; called by muse, mutect2
- CATSPER1 | c.901C>G p.Q301E | Missense Mutation (SNP) | VAF 220/700 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV56411405; called by muse, mutect2, varscan2
- CDK16 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.243); catalogued as rs142251178, COSV52093790; called by muse, mutect2, varscan2
- CEP120 | c.2069G>A p.R690K | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100071078; called by muse, mutect2
- CEP68 | c.1210C>G p.P404A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV53125555; called by muse, mutect2, varscan2
- CHGB | c.1301C>A p.T434N | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs772514466, COSV66760775; called by muse, mutect2, varscan2
- CLASP2 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100223406; called by muse, mutect2
- CPAMD8 | c.2690T>A p.V897D (on ENST00000651564; = p.V850D on NM_015692.5) | Missense Mutation (SNP) | VAF 63/114 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV71596757; called by muse, mutect2, varscan2
- CPED1 | c.655C>A p.Q219K | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV60004718; called by muse, mutect2, varscan2
- DENND3 | c.2110C>G p.Q704E | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV99370908; called by muse, mutect2
- DNAJC27 | c.529-1G>C p.X177_splice | Splice Site (SNP) | VAF 23/80 reads (29%) | catalogued as COSV53095463, COSV53096436; called by muse, mutect2, varscan2
- EIPR1 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.099); catalogued as COSV66130581; called by muse, mutect2, varscan2
- ERN2 | c.1905C>A p.H635Q | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55622619; called by muse, mutect2, varscan2
- EYS | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV100676410, COSV60980288; called by muse, mutect2
- FAM228A | c.256C>T p.R86* | Nonsense Mutation (SNP) | VAF 32/159 reads (20%) | catalogued as rs755379430, COSV54595486; called by muse, mutect2, varscan2
- GGA2 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.91); catalogued as rs1360292836, COSV59168914; called by muse, mutect2, varscan2
- GPATCH8 | c.1939C>A p.P647T | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.057); catalogued as COSV59195508; called by muse, mutect2, varscan2
- GPR161 | c.751A>G p.S251G | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); catalogued as COSV54791512; called by muse, mutect2, varscan2
- HELZ | c.4463C>T p.S1488L | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs777619260, COSV62378210; called by muse, mutect2, varscan2
- HIP1 | c.2572C>G p.P858A | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as COSV61183150, COSV61187387; called by muse, mutect2, varscan2
- HIVEP3 | c.6232G>A p.E2078K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.073); catalogued as rs377282990; called by muse, mutect2, varscan2
- HPSE | c.1142T>A p.M381K | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV60987238; called by muse, mutect2, varscan2
- IGSF5 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV66030592; called by muse, mutect2, varscan2
- IL17B | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs777464695, COSV55783132; called by muse, mutect2, varscan2
- IL4R | c.1805G>C p.G602A | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as COSV99405000; called by muse, mutect2, varscan2
- IQGAP3 | c.4091G>A p.S1364N | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.318); catalogued as COSV63252330; called by muse, mutect2, varscan2
- KRT4 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs377329227, COSV53409461; ClinVar: benign; called by muse, mutect2
- LHFPL1 | c.484A>G p.T162A | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.31); catalogued as COSV64333610; called by muse, varscan2
- LONP2 | c.872T>G p.V291G | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.031); catalogued as COSV53523311; called by muse, mutect2, varscan2
- MADD | c.4099G>A p.E1367K | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60625366; called by muse, mutect2, varscan2
- MAP2 | c.3051G>T p.K1017N | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.658); catalogued as COSV52280006, COSV52295115; called by muse, mutect2, varscan2
- MARF1 | c.4864G>A p.V1622I | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs200947981; called by muse, mutect2, varscan2
- MOV10 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53518137; called by muse, mutect2, varscan2
- MYCN | c.1201T>A p.F401I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55259172; called by muse, mutect2, varscan2
- NAV1 | c.510G>T p.K170N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as COSV55219418; called by muse, mutect2, varscan2
- NCOR1 | c.6688C>T p.Q2230* | Nonsense Mutation (SNP) | VAF 37/68 reads (54%) | catalogued as COSV51979479; called by muse, mutect2, varscan2
- NLRP9 | c.1057A>G p.R353G | Missense Mutation (SNP) | VAF 95/217 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV60464350; called by muse, mutect2, varscan2
- NPHS1 | c.2831C>G p.P944R | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62288438; called by muse, varscan2
- NTRK1 | c.1876C>A p.Q626K | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV62326251; called by muse, mutect2, varscan2
- NXF5 | n.1280-2A>G | Splice Site (SNP) | VAF 95/216 reads (44%) | catalogued as COSV53791558, COSV53793819; called by muse, mutect2, varscan2
- OTOP2 | c.1346C>G p.T449S | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.09); catalogued as COSV58882281; called by muse, mutect2, varscan2
- PHF3 | c.3730C>T p.Q1244* | Nonsense Mutation (SNP) | VAF 19/152 reads (13%) | catalogued as COSV100013304; called by muse, mutect2
- PKHD1 | c.5832C>A p.D1944E | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753429413, COSV61881295; called by muse, mutect2, varscan2
- PKHD1L1 | c.632T>A p.L211Q | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101006083; called by muse, mutect2, varscan2
- PLCH1 | c.1895G>C p.R632T (on ENST00000340059 / NM_001130960.2; = p.R644T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/413 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs775508925, COSV58201104; called by muse, varscan2
- PMEPA1 | c.593A>T p.D198V | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1369834704, COSV55694135; called by muse, varscan2
- PSMC4 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.283); catalogued as COSV50095959; called by muse, mutect2, varscan2
- PTPRG | c.3364G>A p.G1122R | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV55646201; called by muse, mutect2, varscan2
- RAB40A | c.19C>A p.P7T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV58491471; called by muse, mutect2, varscan2
- RENBP | c.216A>G p.V72= | Splice Region (SNP) | VAF 8/12 reads (67%) | catalogued as COSV60073649; called by muse, mutect2, varscan2
- ROR1 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as rs749580497, COSV64285967; called by muse, mutect2, varscan2
- SEMA4G | c.1655G>C p.R552T (on ENST00000370250; = p.R557T on NM_017893.3) | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.268); catalogued as COSV52969124; called by muse, mutect2, varscan2
- SGCE | c.837G>C p.Q279H (on ENST00000647096; = p.Q243H on NM_003919.3) | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV56017879; called by muse, mutect2, varscan2
- SLC10A1 | c.797G>A p.C266Y | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772762685, COSV53682808; called by muse, mutect2, varscan2
- SLC17A3 | c.705G>T p.M235I | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV57760433; called by muse, mutect2, varscan2
- SLC31A1 | c.360C>G p.H120Q | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.147); catalogued as rs757926731, COSV65264747; called by muse, mutect2, varscan2
- SLC35E1 | c.738C>G p.F246L | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.621); catalogued as COSV101290772, COSV68735970; called by muse, mutect2
- SPTA1 | c.5269C>T p.R1757C | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754598605, COSV63754961; called by muse, mutect2, varscan2
- TCN1 | c.681G>C p.K227N | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV57252116; called by muse, mutect2, varscan2
- TEX14 | c.254G>C p.R85P | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53617807, COSV53619272; called by muse, mutect2, varscan2
- TRPC5 | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.828); catalogued as COSV53293487; called by muse, mutect2, varscan2
- TTN | c.60077G>C p.R20026P (on ENST00000591111; = p.R12602P on NM_003319.4) | Missense Mutation (SNP) | VAF 31/103 reads (30%) | PolyPhen possibly damaging (0.614); catalogued as COSV60077580, COSV60132214; called by muse, mutect2, varscan2
- UTP14C | c.2203G>T p.D735Y | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV73000706; called by muse, mutect2, varscan2
- YTHDF3 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as COSV72773647; called by muse, mutect2, varscan2
- ZC3H15 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV61922628; called by muse, mutect2, varscan2
- ATP5F1C | c.362_379del p.L121_E127delinsQ | In Frame Del (DEL) | VAF 51/248 reads (21%) | called by mutect2, pindel, varscan2
- CENPF | c.5260_5273del p.P1754Tfs*13 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel
- COL23A1 | c.465_468+19del p.X155_splice | Splice Site (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- FAM98A | c.889-4_889-2delinsCT p.X297_splice | Splice Site (DEL) | VAF 12/94 reads (13%) | called by pindel, varscan2*
- IL1R2 | c.982_1000del p.V328Ffs*50 | Frame Shift Del (DEL) | VAF 31/99 reads (31%) | called by mutect2, pindel, varscan2
- NMNAT2 | c.403del p.Q135Sfs*42 | Frame Shift Del (DEL) | VAF 47/281 reads (17%) | called by mutect2, pindel, varscan2
- NPAS3 | c.1008_1017del p.V337Tfs*17 (on ENST00000356141 / NM_001164749.2; = p.V305Tfs*17 on NM_022123.3) | Frame Shift Del (DEL) | VAF 24/117 reads (21%) | called by mutect2, pindel, varscan2
- OR7A10 | c.539_552del p.E180Gfs*7 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- SQOR | c.1080_1098del p.S361Kfs*16 | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | called by mutect2, pindel, varscan2
- TEX15 | c.4843_4847del p.A1615Sfs*10 (on ENST00000256246; = p.A1998Sfs*10 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 22/41 reads (54%) | called by mutect2, pindel, varscan2
- TRAV9-2 | c.329C>G p.A110G | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TTN | c.15652_15661del p.A5218Lfs*2 (on ENST00000591111; = p.A4291Lfs*2 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- UGT8 | c.1041_1042+4del p.X347_splice | Splice Site (DEL) | VAF 88/157 reads (56%) | called by mutect2, pindel*, varscan2*
- ZNF658 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- ADGRG4 | c.9042G>C p.G3014= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV99795390; called by muse, mutect2, varscan2
- ARFGEF1 | c.1173T>C p.D391= | Silent (SNP) | VAF 40/272 reads (15%) | catalogued as COSV51610621; called by muse, mutect2, varscan2
- ASMTL | c.292C>T p.L98= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as rs1327675598, COSV67243589; called by muse, mutect2, varscan2
- ATL2 | c.1113A>G p.P371= | Silent (SNP) | VAF 59/246 reads (24%) | catalogued as COSV60053046; called by muse, mutect2, varscan2
- CALD1 | c.2334C>G p.L778= (on ENST00000361675 / NM_033138.4; = p.L523= on NM_004342.7) | Silent (SNP) | VAF 8/219 reads (4%) | called by muse, mutect2
- CDK5RAP2 | c.3453A>G p.E1151= | Silent (SNP) | VAF 133/280 reads (48%) | catalogued as COSV62575231; called by muse, mutect2, varscan2
- CLDN17 | c.99A>T p.S33= | Silent (SNP) | VAF 27/137 reads (20%) | catalogued as COSV54523377; called by muse, mutect2, varscan2
- COL5A3 | c.3138C>T p.G1046= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs751164972, COSV53406336, COSV53412589; called by muse, mutect2, varscan2
- CYP3A4 | c.516G>A p.L172= | Silent (SNP) | VAF 24/155 reads (15%) | catalogued as COSV100315640; called by muse, mutect2, varscan2
- DACH1 | c.912C>T p.I304= | Silent (SNP) | VAF 20/218 reads (9%) | catalogued as COSV100498318; called by muse, mutect2
- DUSP7 | c.864C>T p.G288= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs373923494; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1698G>A p.R566= (on ENST00000361735 / NM_015935.5; = p.R480= on NM_014955.3) | Silent (SNP) | VAF 29/168 reads (17%) | catalogued as COSV62283278; called by muse, mutect2, varscan2
- ERG | c.156C>G p.S52= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV55733955; called by muse, mutect2, varscan2
- F8 | c.6528C>T p.S2176= | Silent (SNP) | VAF 29/254 reads (11%) | catalogued as CM053870, COSV57705493; called by muse, mutect2, varscan2
- FREM2 | c.4992C>A p.A1664= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99748646; called by muse, mutect2
- FZD5 | c.270C>T p.Y90= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- GPR61 | c.705C>G p.A235= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV63983941; called by muse, mutect2, varscan2
- GRIA1 | c.624C>A p.R208= | Silent (SNP) | VAF 63/270 reads (23%) | catalogued as rs774608617, COSV53608054; called by muse, mutect2, varscan2
- HIVEP2 | c.7326G>A p.K2442= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as COSV50019014, COSV50068620; called by muse, mutect2, varscan2
- HLF | c.16C>A p.R6= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV99872120; called by muse, mutect2
- KCNH5 | c.207T>C p.Y69= | Silent (SNP) | VAF 30/209 reads (14%) | catalogued as COSV59763578; called by muse, mutect2, varscan2
- LAS1L | c.2103C>T p.V701= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs1030921314, COSV100161727; called by muse, mutect2, varscan2
- MDGA2 | c.1344A>T p.P448= (on ENST00000399232 / NM_001113498.2; = p.P150= on NM_182830.4) | Silent (SNP) | VAF 50/85 reads (59%) | catalogued as COSV62097546; called by muse, mutect2, varscan2
- MRPL45 | c.471T>C p.H157= | Silent (SNP) | VAF 20/146 reads (14%) | catalogued as rs780532522; called by muse, mutect2
- MUC16 | c.21456T>C p.P7152= | Silent (SNP) | VAF 206/705 reads (29%) | catalogued as COSV67473675; called by muse, varscan2
- MYH9 | c.5109G>C p.R1703= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV53387923; called by muse, mutect2, varscan2
- PDCD2L | c.357A>C p.A119= | Silent (SNP) | VAF 69/139 reads (50%) | catalogued as COSV99874983; called by muse, mutect2, varscan2
- PRF1 | c.132C>T p.A44= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs181323749, COSV64615182; called by muse, mutect2, varscan2
- RYR2 | c.11877G>T p.S3959= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs754610647, COSV100770010; called by muse, mutect2
- SLC25A44 | c.120C>A p.L40= | Silent (SNP) | VAF 75/404 reads (19%) | catalogued as COSV63961884; called by muse, mutect2, varscan2
- VMP1 | c.1116C>G p.V372= | Silent (SNP) | VAF 54/434 reads (12%) | catalogued as rs111262775, COSV51868729; called by muse, mutect2, varscan2
- YY2 | c.1032C>G p.P344= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV63411794; called by muse, mutect2, varscan2
- ZNF749 | c.51C>T p.F17= | Silent (SNP) | VAF 165/326 reads (51%) | catalogued as rs903820291, COSV61946531; called by muse, mutect2, varscan2
- ZRANB3 | c.1506T>G p.S502= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as COSV51504961; called by muse, mutect2, varscan2
- PPP1R9A | c.2757+607G>A | Intron (SNP) | VAF 15/93 reads (16%) | catalogued as rs374685907; called by muse, mutect2, varscan2
- YY1AP1 | c.927-25C>G | Intron (SNP) | VAF 117/520 reads (23%) | catalogued as COSV55122142; called by muse, mutect2, varscan2
